Somatic mutation profile of tumor specimen 0DWTC1 from CCDI case PBCPKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Labium majus; Age at diagnosis: 1.5 years (556 days).
Specimen 0DWTC1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e0cdaa9-18f8-4b84-8bd8-457d17c98c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWTAC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a4567ce-6d76-496f-b750-85f513dce3d6

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 2, Frame Shift Del 1, Intron 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1649T>A p.V550E | Missense Mutation (SNP) | VAF 385/411 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519793; ClinVar: likely pathogenic; called by muse, varscan2
- NEXMIF | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 176/366 reads (48%) | catalogued as rs886041971, COSV50157409, COSV99280435; ClinVar: pathogenic; called by muse, varscan2
- CSMD1 | c.1222C>G p.R408G (on ENST00000520002; = p.R407G on NM_033225.6) | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs376057777, COSV68211442; called by muse, varscan2
- FGFR4 | c.1949G>C p.R650P | Missense Mutation (SNP) | VAF 179/209 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52801476; called by muse, varscan2
- ME1 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs1248662777; called by muse, varscan2
- PPFIA4 | c.2644C>T p.R882W (on ENST00000447715; = p.R883W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753391903; called by muse, varscan2
- PSMD1 | c.1475A>G p.D492G | Missense Mutation (SNP) | VAF 108/462 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.152); catalogued as rs779475139; called by muse, varscan2
- SALL3 | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs769002198, COSV73306185; called by muse, varscan2
- ZNF827 | c.1768A>G p.M590V | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs767194473; called by muse, varscan2
- ABCB1 | c.2409G>T p.W803C | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- DSG4 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HLA-G | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.301); called by muse, varscan2
- IGSF22 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 66/562 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, varscan2
- NPSR1 | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 202/296 reads (68%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, varscan2
- PRR36 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.49); called by muse, varscan2
- RPLP1 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, varscan2
- TRIM52 | c.725_726del p.K242Rfs*54 | Frame Shift Del (DEL) | VAF 42/438 reads (10%) | called by pindel, varscan2
- GALNT2 | c.945G>A p.K315= | Silent (SNP) | VAF 154/392 reads (39%) | called by muse, varscan2
- UPK1B | c.663G>T p.L221= | Silent (SNP) | VAF 72/270 reads (27%) | called by muse, varscan2
- BANP | c.*57C>T | 3'UTR (SNP) | VAF 52/119 reads (44%) | catalogued as rs1222608147, COSV99620447; called by muse, varscan2
- ZSCAN32 | c.695-514G>A | Intron (SNP) | VAF 62/141 reads (44%) | called by muse, varscan2
